Surgical pathology report (de-identified scan), TCGA case TCGA-77-A5GB, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-A5GB-01B (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, Squamous cell,
Keratinizing NOS 8071/3

Site: Lung, upper lobe (34.1)
QV 2/7/13

Histopathology Report

HISTORY

Lingulectomy for squamous cell carcinoma.

MACROSCOPIC

One specimen received.

The specimen is labelled 'L wedge resection lingula' and consists of a wedge resection of lung measuring in its partially inflated state 115 x 90 x 35 mm. A staple line is present at the proximal margin measuring 85 mm in length. The pleural surface contains two separate ragged/indurated areas. The largest measures 35 x 25 mm and is roughened. The second smaller area measures 17 mm in greatest dimension and has a punched out full thickness defect in the pleura. The pleura surrounding these roughened areas shows diffuse thickening. The cut surface shows a pleural-based peripheral tumour. It has an ill-defined outline with prominent adjacent collapse and consolidation. The tumour measures approximately 35 x 31 x 19 mm. It appears to directly involve the two disrupted pleural surfaces described previously. The tumour lies 15 mm from the nearest surgical resection margin. The cut surface of the rest of the lung parenchyma shows extensive obstructive changes. There are small firm nodules within this ranging in size from 1 to 5 mm in greatest dimension. They may represent separate tumour foci. There is also mild emphysema. [1A-1B, tumour including resection margin; 1C-1D, RS tumour adjacent to smaller full thickness pleural defect; 1E, RS tumour adjacent to intact pleura next to small defect; 1F, RS tumour adjacent to larger full thickness pleural defect; 1G, RS possible separate tumour foci within consolidation; 1H, RS relatively normal lung.]

MICROSCOPIC

Sections show a moderately differentiated keratinising squamous cell carcinoma. It shows areas of necrosis and is associated with a florid inflammatory response. Invasion of the visceral pleura is confirmed and carcinoma is present on the inked surface of the disrupted pleura. The stapled surgical resection margin is well clear of malignancy. Tumour surrounds and compresses a number of blood vessels, and there is focal vascular invasion. No lymphatic or perineural invasion is identified. The surrounding lung is confirmed to show organising obstructive pneumonitis. The nodules noted macroscopically appear to represent foci of bronchiectasis, organising pneumonia and localised subpleural honeycomb change. No tumour is identified within these areas. There is interstitial fibrosis in these areas and there are a few foci of fibroblastic proliferation reminiscent of the fibroblastic foci of UIP; however the section of normal appearing lung shows only emphysema with no features to suggest an established interstitial pneumonitis. No lymph nodes are included.

SUMMARY

Lingulectomy:

Moderately differentiated squamous cell carcinoma, 35 mm in diameter.

Pleural invasion present with disruption and tumour on pleural surface.

[page 2 of 2]
Vascular invasion present.
No lymphatic or perineural invasion identified.
No lymph nodes included.
Pathological stage T2a Nx.

Repc

T-28000 M-80703 P1-03000

	ANATOMICAL PATHOLOGY
--	----------------------

Criteria	hw 3/29/13	Adenocarcinoma - NOS	Yes	No

Source: NCI Genomic Data Commons file 46f79a5f-0024-4cd4-b5ba-441ad5cac6a9 (TCGA-77-A5GB.15DE0F5C-3C0D-4EAB-90D2-5CC758066751.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).